Somatic mutation profile of tumor specimen TCGA-FD-A62P-01A (aliquot TCGA-FD-A62P-01A-32D-A30E-08) from TCGA case TCGA-FD-A62P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,843 days).
Specimen TCGA-FD-A62P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55411818-f58c-4e80-b942-569b61b4b9cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A62P-10A (Blood Derived Normal), aliquot TCGA-FD-A62P-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc7e37d-4b47-470d-abc9-d1e273432d60

The open-access MAF lists 408 somatic variants for this specimen: 314 protein-altering or splice-affecting, 88 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 88, Nonsense Mutation 29, Splice Site 7, Intron 5, Frame Shift Del 2, In Frame Del 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55452713, COSV55455449; called by muse, mutect2, varscan2
- RHOA | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs11552761, COSV69041529, COSV69041693, COSV69041915, COSV69043569; called by muse, mutect2, varscan2
- SF3B1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59206538, COSV59210925; called by muse, mutect2, varscan2
- A1BG | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); catalogued as rs200002683, COSV54050251; called by muse, mutect2, varscan2
- AAAS | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as CD024030, COSV52932440; called by muse, mutect2, varscan2
- AADAC | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV51758562, COSV99233259; called by muse, mutect2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCD3 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64642549; called by muse, mutect2, varscan2
- ACMSD | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99299463; called by muse, mutect2, varscan2
- ACSF3 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58077256; called by muse, mutect2, varscan2
- ACSM2B | c.1098G>A p.T366= | Splice Region (SNP) | VAF 88/306 reads (29%) | catalogued as rs772046996, COSV61657196; called by muse, mutect2, varscan2
- ADGRL3 | c.2368G>A p.G790R (on ENST00000506720 / NM_001322402.2; = p.G722R on NM_015236.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.457); catalogued as rs1217103808, COSV101547384, COSV72229766; called by muse, mutect2
- AGO4 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs1334541365, COSV64616630; called by muse, mutect2, varscan2
- AHI1 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99663690; called by muse, mutect2, varscan2
- AHNAK | c.16907A>C p.Q5636P | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57207275; called by muse, mutect2, varscan2
- AHNAK | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV57207304; called by muse, mutect2
- AKAP8 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99512163; called by muse, mutect2, varscan2
- AL121899.2 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs766632444, COSV67350020; called by muse, mutect2, varscan2
- AMH | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99678095; called by muse, mutect2, varscan2
- ANK2 | c.8512G>C p.D2838H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.148); catalogued as COSV52151649, COSV52162111; called by muse, mutect2
- ARHGEF18 | c.466C>G p.P156A (on ENST00000359920 / NM_001130955.2; = p.P52A on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs765852033, COSV60468082; called by muse, varscan2
- ARID1A | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.112); catalogued as COSV61373909; called by muse, mutect2, varscan2
- ARID1A | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- ARRB1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100758067, COSV63574751; called by muse, mutect2, varscan2
- ATP1B2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs757566775, COSV51515140; called by muse, mutect2
- ATP6V1C2 | c.290T>C p.L97S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55358645; called by muse, mutect2
- ATXN3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as rs772732276, COSV100515613; called by muse, varscan2
- AVPR2 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as rs782160409, COSV61685929; called by muse, mutect2, varscan2
- BAIAP3 | c.1276A>T p.S426C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); catalogued as COSV60978541; called by muse, mutect2, varscan2
- BEND6 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV66068378; called by muse, mutect2, varscan2
- C1orf21 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV52403208; called by muse, mutect2, varscan2
- C2CD5 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV61723634; called by muse, mutect2, varscan2
- C4B | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs202120998, COSV70931100; called by muse, mutect2, varscan2
- CACNB4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as rs1304491659, COSV52390979; called by muse, mutect2, varscan2
- CADPS | c.1776C>G p.F592L | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51871765; called by muse, mutect2
- CATSPER1 | c.965C>G p.T322S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56409455; called by muse, mutect2, varscan2
- CATSPER1 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV56409467; called by muse, mutect2, varscan2
- CCDC178 | c.1193G>C p.R398T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as COSV55764947; called by muse, mutect2, varscan2
- CCDC69 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV62599243; called by muse, mutect2
- CD163 | c.2378C>A p.S793Y | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1201443489, COSV63130616, COSV63130688; called by muse, mutect2
- CD209 | c.47-1G>C p.X16_splice | Splice Site (SNP) | VAF 40/516 reads (8%) | catalogued as COSV52651099; called by muse, mutect2
- CD9 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as rs763242756, COSV99153204; called by muse, mutect2, varscan2
- CDH12 | c.1712T>C p.I571T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV66393886; called by muse, mutect2, varscan2
- CDH19 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1366186991, COSV50955556; called by muse, mutect2, varscan2
- CDH19 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); catalogued as rs533652186, COSV50955575; called by muse, mutect2
- CDK6 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as COSV56006230, COSV56010583; called by muse, mutect2
- CDR1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1378211844, COSV100983444, COSV65163967; called by muse, mutect2, varscan2
- CEND1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57192507; called by muse, mutect2, varscan2
- CEP135 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99954884; called by muse, mutect2
- CEP68 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53123944; called by muse, mutect2, varscan2
- CEP68 | c.1290C>A p.H430Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV53123954; called by muse, mutect2, varscan2
- CEPT1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV100853509; called by muse, mutect2, varscan2
- CFAP70 | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV60281786; called by muse, mutect2, varscan2
- CHD4 | c.1735G>A p.E579K (on ENST00000357008 / NM_001363606.2; = p.E592K on NM_001273.5) | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV58896716; called by muse, mutect2
- CHRDL1 | c.550G>C p.D184H (on ENST00000372045; = p.D190H on NM_145234.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV54323646; called by muse, mutect2, varscan2
- CILP2 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV52273388; called by muse, varscan2
- CLCN3 | c.2160G>T p.R720S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV61626594; called by mutect2, varscan2
- CLDN1 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55043638; called by muse, mutect2, varscan2
- CLK2 | c.943G>C p.E315Q (on ENST00000368361 / NM_001294339.2; = p.E314Q on NM_003993.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV100226803, COSV56944175; called by muse, mutect2, varscan2
- CLK2 | c.649G>C p.E217Q (on ENST00000368361 / NM_001294339.2; = p.E216Q on NM_003993.4) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV62876735; called by muse, varscan2
- CLSTN3 | c.529T>A p.Y177N | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56934739, COSV99867818; called by muse, mutect2, varscan2
- CNTN1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV61637450; called by muse, mutect2
- COL1A1 | c.3478G>A p.G1160S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56803234; called by muse, mutect2
- COPS3 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV52004603; called by muse, mutect2, varscan2
- CRACDL | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV67407051, COSV67409490; called by mutect2, varscan2
- CSNK2A1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99424702; called by muse, mutect2
- CSPG4 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1387915856, COSV57892314; called by muse, mutect2
- CTAGE1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV101194675; called by muse, mutect2, varscan2
- CXCR6 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV56114573; called by muse, mutect2, varscan2
- CXorf38 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59947367; called by muse, mutect2, varscan2
- CYP11B2 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as rs780392562, COSV59995164; called by muse, mutect2, varscan2
- DBN1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52788285; called by muse, mutect2, varscan2
- DCAF8 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100470794; called by muse, mutect2
- DCHS1 | c.8170C>T p.L2724F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs866643933, COSV54996534; called by muse, mutect2, varscan2
- DENND2B | c.2612A>G p.H871R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58202113; called by muse, mutect2, varscan2
- DENND5B | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60900831; called by muse, mutect2, varscan2
- DERL2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV50147051; called by muse, mutect2, varscan2
- DMRTA1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV57923918; called by muse, mutect2, varscan2
- DNAJB13 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60268842; called by muse, mutect2, varscan2
- DNAJC1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65409795; called by muse, mutect2, varscan2
- DNER | c.1680C>A p.S560R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as rs200801433, COSV100517942, COSV59162221; called by muse, mutect2
- DNM2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV58958393; called by muse, mutect2, varscan2
- DPYSL3 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs777564671, COSV58323892, COSV58325048; called by muse, mutect2, varscan2
- DYNC1I2 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55524927; called by muse, mutect2, varscan2
- DZANK1 | c.952G>C p.E318Q (on ENST00000262547 / NM_001099407.1; = p.E119Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52749040; called by muse, mutect2
- E2F8 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51462396; called by muse, mutect2, varscan2
- EAF1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777059936, COSV67657227; called by muse, mutect2
- ECD | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV65898969; called by muse, mutect2
- ECHS1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63906536; called by muse, mutect2
- EHBP1L1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774880146, COSV58571952; called by muse, mutect2, varscan2
- EIF2AK2 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV51795325; called by muse, mutect2, varscan2
- EIF2B4 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52006981; called by muse, mutect2, varscan2
- EIF5A | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59748064; called by muse, mutect2, varscan2
- EML5 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100716170; called by muse, mutect2, varscan2
- ENAM | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.347); catalogued as COSV68535497; called by muse, mutect2
- ERC2 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 19/166 reads (11%) | catalogued as COSV99889794; called by muse, mutect2, varscan2
- ERICH1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.45); catalogued as COSV50637465; called by muse, mutect2
- ETS2 | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1341661839, COSV62872539; called by muse, mutect2
- EXOC8 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV50477707, COSV50478072; called by muse, mutect2, varscan2
- EZH1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV70548935; called by muse, mutect2, varscan2
- FAM71B | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57228084; called by muse, mutect2, varscan2
- FBN3 | c.5794G>C p.E1932Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54456058; called by muse, mutect2
- FBXO43 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101413964, COSV71053577; called by muse, mutect2, varscan2
- FGF9 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.316); catalogued as COSV66644258; called by muse, mutect2, varscan2
- FH | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV63817754; called by muse, mutect2, varscan2
- FLNB | c.5974A>G p.I1992V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.959); catalogued as rs764333955, COSV55873567; called by muse, mutect2, varscan2
- FLT3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV54047818; called by muse, mutect2, varscan2
- FMO4 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV63000745; called by muse, mutect2, varscan2
- G2E3 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52839171; called by muse, mutect2, varscan2
- G6PC2 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56371734; called by muse, mutect2, varscan2
- GADL1 | c.996C>A p.H332Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56976372; called by muse, mutect2, varscan2
- GCN1 | c.5638G>C p.E1880Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV56105205; called by muse, mutect2, varscan2
- GIPC3 | c.936G>C p.Q312H (on ENST00000644946; = p.R308T on NM_133261.3) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1199684186; called by muse, mutect2
- GJB3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV64904447; called by muse, mutect2
- GOLGA4 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100729152; called by muse, mutect2
- GOLGB1 | c.8764C>A p.Q2922K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV61463182; called by muse, mutect2, varscan2
- GOLGB1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV61463189; called by muse, mutect2
- GRHL1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV61406959; called by muse, mutect2, varscan2
- GRID1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60018923; called by muse, mutect2, varscan2
- GRIN2D | c.3353C>T p.S1118L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV53518101; called by muse, mutect2, varscan2
- GRK6 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62682081; called by muse, mutect2
- GTF2H1 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 21/136 reads (15%) | catalogued as COSV56377865; called by muse, mutect2, varscan2
- HCN3 | c.187C>G p.R63G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100751768, COSV62876739; called by muse, mutect2, varscan2
- HDAC6 | c.3382G>C p.D1128H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57806460; called by muse, mutect2, varscan2
- HDAC9 | c.3113C>T p.S1038F (on ENST00000441542 / NM_178425.3; = p.S1035F on NM_178423.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67769650; called by muse, mutect2, varscan2
- HECTD4 | c.12064G>A p.E4022K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.037); catalogued as COSV66388681; called by muse, mutect2, varscan2
- HECW2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as COSV53652879; called by muse, mutect2, varscan2
- HERC4 | c.2569G>C p.E857Q (on ENST00000395198 / NM_022079.3; = p.E849Q on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53269307; called by muse, mutect2, varscan2
- HGSNAT | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52816582; called by muse, mutect2
- HK1 | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as COSV100067944; called by muse, mutect2
- HMGCR | c.2249A>T p.N750I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55314895, COSV55314959; called by muse, mutect2, varscan2
- HNRNPUL1 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV54560906; called by muse, mutect2, varscan2
- HYDIN | c.14992G>T p.E4998* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV101125219, COSV66638014; called by muse, mutect2, varscan2
- IGSF1 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); catalogued as COSV63836647; called by muse, mutect2, varscan2
- IGSF21 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs748938162, COSV52127521; called by muse, mutect2
- ILVBL | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54618439; called by muse, mutect2, varscan2
- INPP5F | c.3002C>G p.S1001* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100740385; called by muse, mutect2
- IQCE | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100383728, COSV58078327; called by muse, mutect2, varscan2
- ITPR3 | c.2584G>C p.E862Q | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65406958; called by muse, mutect2, varscan2
- ITSN1 | c.2824G>A p.V942I | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs370969706; called by muse, mutect2
- JTB | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV55131691; called by muse, mutect2
- JUP | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV100159800; called by muse, mutect2
- KATNB1 | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101109981; called by muse, varscan2
- KCNH8 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV60458868; called by muse, mutect2, varscan2
- KDM3A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57219297, COSV57220428; called by muse, mutect2, varscan2
- KHDC3L | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1241027501, COSV64863056; called by muse, mutect2, varscan2
- KMT2D | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV99985669; called by muse, mutect2, varscan2
- KRT13 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55839373; called by muse, mutect2
- KRTAP10-10 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV59955536; called by muse, mutect2, varscan2
- L1CAM | c.2464G>C p.E822Q | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV62827318; called by muse, mutect2, varscan2
- LACTB2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV52567751, COSV52568290; called by muse, mutect2
- LDLRAD2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1311599474, COSV60827747; called by muse, mutect2
- LIME1 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.403); catalogued as COSV55507812; called by muse, mutect2, varscan2
- LSR | c.1331C>T p.S444F (on ENST00000361790; = p.S425F on NM_015925.6) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.018); catalogued as rs531278587, COSV55886620; called by muse, mutect2
- LSR | c.1333C>T p.R445W (on ENST00000361790; = p.R426W on NM_015925.6) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1416375657, COSV55886624; called by muse, mutect2
- MADD | c.1305G>C p.M435I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV60621655; called by muse, mutect2
- MADD | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV60621663; called by muse, mutect2
- MADD | c.2467G>C p.E823Q | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV60621674; called by muse, mutect2
- MAP1A | c.4456G>C p.E1486Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1253978465, COSV55807110; called by muse, mutect2, varscan2
- MAP3K5 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100753255; called by muse, mutect2
- MAP7 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV63418180; called by muse, mutect2, varscan2
- MC5R | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 100/648 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61254181; called by muse, mutect2, varscan2
- MGARP | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV67449136; called by muse, mutect2
- MIA3 | c.3985C>T p.Q1329* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100485215; called by muse, mutect2, varscan2
- MINAR1 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); catalogued as COSV59581549; called by muse, mutect2
- MMP13 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1289127552, COSV52823326; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56617706; called by muse, mutect2, varscan2
- MPND | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV53656283; called by muse, mutect2, varscan2
- MRPL37 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1225266612, COSV55276851; called by muse, mutect2, varscan2
- MTF1 | c.1602G>C p.Q534H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as COSV65988571; called by muse, mutect2
- MTSS2 | c.458-1G>C p.X153_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as COSV58697865; called by muse, mutect2, varscan2
- MTSS2 | c.383-1G>C p.X128_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100116694; called by muse, mutect2
- MYH8 | c.4921G>A p.E1641K | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67961624, COSV67969978; called by muse, mutect2, varscan2
- MYLK | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs371825849, COSV60606733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1411415711, COSV55683860; called by muse, mutect2, varscan2
- NCAPD2 | c.3777C>G p.I1259M | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV57520681; called by muse, mutect2, varscan2
- NCOA2 | c.2143C>G p.L715V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.91); catalogued as COSV71763676; called by muse, mutect2, varscan2
- NIPBL | c.6815C>T p.S2272L | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56945850; called by muse, mutect2, varscan2
- NPAS2 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | catalogued as COSV59561914; called by muse, mutect2
- NRXN3 | c.1221+1G>C p.X407_splice (on ENST00000335750 / NM_001330195.2; = p.X34_splice on NM_004796.6) | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100208896; called by muse, mutect2
- NSD3 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57617713; called by muse, varscan2
- NUMA1 | c.5279C>G p.S1760C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1197957958, COSV99474978; called by muse, mutect2
- NUP205 | c.2983C>G p.L995V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53656415; called by muse, varscan2
- NUP214 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs1236764896, COSV63908316; called by muse, mutect2, varscan2
- OGDH | c.3023G>C p.R1008P | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV56047071, COSV99759027; called by muse, mutect2, varscan2
- OPN3 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.1); catalogued as COSV59363084; called by muse, mutect2, varscan2
- OXCT1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV52168538, COSV52176412; called by muse, mutect2
- OXER1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV54310154; called by muse, mutect2, varscan2
- OXNAD1 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV53269313; called by muse, mutect2
- P4HA1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54958041; called by muse, mutect2, varscan2
- PARP14 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV72111688; called by muse, mutect2, varscan2
- PARP15 | c.1569G>C p.E523D (on ENST00000464300 / NM_001113523.3; = p.E289D on NM_152615.2) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV59971750; called by muse, mutect2, varscan2
- PCDH8 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.023); catalogued as COSV58811360; called by muse, mutect2
- PCDHA6 | c.1380C>A p.Y460* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | catalogued as COSV100971798; called by muse, mutect2, varscan2
- PCDHGA6 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.072); catalogued as COSV53915776; called by muse, mutect2
- PCDHGA7 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53915791; called by muse, mutect2, varscan2
- PDE4A | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99535183; called by muse, mutect2
- PDZRN4 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); catalogued as COSV101284701; called by muse, mutect2
- PGM5 | c.262-1G>T p.X88_splice | Splice Site (SNP) | VAF 10/96 reads (10%) | catalogued as COSV67163234, COSV67163617; called by muse, varscan2
- PGM5 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV67163238; called by muse, mutect2, varscan2
- PHOSPHO2 | c.34A>C p.T12P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55866223; called by muse, mutect2, varscan2
- PHTF1 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63367017; called by muse, mutect2, varscan2
- PIK3R5 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.636); catalogued as COSV52651526; called by muse, mutect2, varscan2
- PLCB3 | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs530167219, COSV54186605; called by muse, mutect2, varscan2
- PLCH2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1353252987, COSV53940286; called by muse, mutect2, varscan2
- PLXNA2 | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs1175753605, COSV100885915; called by muse, mutect2
- PLXNA2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV65438554; called by muse, mutect2, varscan2
- PLXNA2 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 62/157 reads (39%) | catalogued as COSV100885917; called by muse, mutect2, varscan2
- PLXNA4 | c.2870C>G p.S957* | Nonsense Mutation (SNP) | VAF 87/297 reads (29%) | catalogued as COSV100326997, COSV58124858; called by muse, mutect2, varscan2
- POLA1 | c.3748C>G p.H1250D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV100985778; called by muse, mutect2, varscan2
- POLG2 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV73376867; called by muse, mutect2, varscan2
- POLG2 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV56748388; called by muse, mutect2, varscan2
- PPFIA3 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100495261; called by muse, mutect2
- PRB2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.908); catalogued as COSV101231411, COSV66982539; called by muse, mutect2
- PREPL | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV53215667; called by muse, mutect2, varscan2
- PREX1 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as COSV64249298; called by muse, mutect2, varscan2
- PRRT3 | c.2860C>T p.R954W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751316734, COSV55976660; called by muse, mutect2, varscan2
- PRRX1 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as COSV53411971; called by muse, mutect2, varscan2
- PSG6 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as COSV51831131, COSV51833294; called by muse, mutect2, varscan2
- PSKH2 | c.1124G>T p.R375M | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV52609667; called by muse, mutect2, varscan2
- PTCH1 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV59467135; called by muse, mutect2, varscan2
- PTGFR | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866779560, COSV66114636, COSV66115438; called by muse, mutect2, varscan2
- PXDN | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs767935865, COSV53229074; called by muse, mutect2, varscan2
- R3HDM1 | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV99926772; called by muse, mutect2, varscan2
- RACGAP1 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV56698790; called by muse, mutect2
- RAI1 | c.3038C>G p.S1013C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV55390645; called by muse, mutect2, varscan2
- RBL1 | c.2811A>G p.I937M | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV60328907; called by muse, mutect2
- RBPJL | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV59212980; called by muse, mutect2, varscan2
- RELN | c.6538G>C p.D2180H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58991449; called by muse, mutect2
- RELN | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.902); catalogued as COSV58991458; called by muse, mutect2, varscan2
- RNF111 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62084380; called by muse, mutect2, varscan2
- RPE65 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52014079; called by muse, mutect2, varscan2
- RPL26 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV53446844; called by muse, mutect2
- RREB1 | c.4527G>C p.K1509N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307044758, COSV58555283; called by muse, mutect2, varscan2
- RTN1 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV50719978; called by muse, mutect2, varscan2
- RTP1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.524); catalogued as COSV56618008; called by muse, mutect2, varscan2
- RTTN | c.3712C>G p.Q1238E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55342617; called by muse, mutect2, varscan2
- RUSC1 | c.1899C>G p.F633L (on ENST00000368352 / NM_001105203.2; = p.F164L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.086); catalogued as COSV52738727; called by muse, varscan2
- SAMD13 | c.260G>C p.R87T (on ENST00000370671; = p.R81T on NM_001010971.3) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65744237, COSV65744525; called by muse, mutect2
- SCN7A | c.3146G>C p.R1049T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV69269941; called by muse, mutect2
- SCNN1G | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55597724; called by muse, mutect2, varscan2
- SEMA3D | c.862-1G>C p.X288_splice | Splice Site (SNP) | VAF 16/141 reads (11%) | catalogued as COSV52398685; called by muse, mutect2
- SEMA7A | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56089634; called by muse, mutect2, varscan2
- SI | c.4129G>C p.E1377Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV52268016, COSV52270226, COSV52276610; called by muse, mutect2, varscan2
- SLC26A8 | c.2149C>G p.L717V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV62885027; called by muse, mutect2, varscan2
- SLC30A8 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69969110; called by muse, mutect2, varscan2
- SLC36A2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1335075738, COSV58861935; called by muse, mutect2, varscan2
- SLX4 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53562220, COSV99567784; called by muse, mutect2
- SNPH | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV60588642; called by muse, mutect2
- SNW1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | catalogued as COSV99473246; called by muse, mutect2, varscan2
- SNW1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV55053631; called by muse, mutect2, varscan2
- SOX30 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV53936210, COSV53936498; called by muse, mutect2, varscan2
- SOX5 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58622670; called by muse, mutect2, varscan2
- SPINDOC | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV53692002; called by muse, mutect2, varscan2
- SRRM2 | c.7717G>A p.E2573K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51940149; called by muse, mutect2, varscan2
- ST7 | c.1345C>G p.L449V (on ENST00000265437 / NM_021908.3; = p.L426V on NM_018412.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55381735; called by muse, mutect2, varscan2
- STAT6 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.091); catalogued as COSV55665827; called by muse, mutect2, varscan2
- SULF2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs549518880, COSV63414827, COSV63419062; called by muse, mutect2, varscan2
- SYNE3 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs1161481401, COSV100516466, COSV62079765; called by muse, mutect2
- SYT4 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54899102; called by muse, mutect2, varscan2
- TBC1D8B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV52176933; called by muse, mutect2, varscan2
- TET1 | c.2702C>T p.S901L | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65382384, COSV65383077; called by muse, mutect2
- TET1 | c.3586C>G p.Q1196E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV65383082; called by muse, mutect2
- THBS2 | c.2397C>G p.C799W | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677642; called by muse, mutect2
- TLL1 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs778788323, COSV50266904; called by mutect2, varscan2
- TLN1 | c.5539G>C p.E1847Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100148137, COSV59205543; called by muse, mutect2, varscan2
- TMED1 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.215); catalogued as COSV53033302; called by muse, mutect2, varscan2
- TMEM132D | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV67159404; called by muse, mutect2, varscan2
- TMEM145 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV100004122, COSV56627196; called by muse, mutect2
- TMEM145 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56624265; called by muse, mutect2, varscan2
- TMEM202 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV58982092; called by muse, mutect2, varscan2
- TRMT1 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs1422482693, COSV53399852; called by muse, mutect2, varscan2
- TSEN2 | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV53188100; called by muse, mutect2, varscan2
- TSEN2 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1223598213, COSV53188120; called by muse, mutect2
- TXNL4B | c.345G>C p.L115F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51702896, COSV51703623; called by muse, mutect2, varscan2
- TYR | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV54472164; called by muse, mutect2, varscan2
- UCHL1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52651276; called by muse, mutect2, varscan2
- UFD1 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV54250612; called by muse, varscan2
- UPF1 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV53194532; called by muse, varscan2
- USP15 | c.850G>A p.E284K (on ENST00000280377 / NM_001351159.2; = p.E255K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.191); catalogued as COSV54789444; called by muse, mutect2, varscan2
- USP21 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV57087339; called by muse, mutect2
- USP24 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53763717; called by muse, mutect2, varscan2
- USP36 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61750819, COSV61753756; called by muse, mutect2
- VWCE | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs779128420, COSV57111401; called by muse, mutect2, varscan2
- WDR5 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62272653; called by muse, mutect2
- WDR7 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV54349943; called by muse, mutect2, varscan2
- WDR83 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54417516; called by muse, mutect2
- WWC3 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66502085; called by muse, mutect2
- ZBED4 | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53464419; called by muse, mutect2, varscan2
- ZBED4 | c.2102C>G p.S701C | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs759113809, COSV53464427; called by muse, mutect2, varscan2
- ZC3H13 | c.2769G>C p.Q923H | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); catalogued as rs955053802, COSV54449850; called by muse, mutect2
- ZEB1 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58039413; called by muse, mutect2, varscan2
- ZFHX3 | c.4970C>G p.T1657S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.04); catalogued as COSV51712339; called by muse, mutect2
- ZKSCAN7 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV56272068; called by muse, mutect2
- ZNF154 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs964182398, COSV101377547; called by muse, mutect2
- ZNF197 | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56076028; called by muse, mutect2, varscan2
- ZNF208 | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV68102366, COSV68109755; called by muse, mutect2, varscan2
- ZNF233 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 35/188 reads (19%) | catalogued as COSV100492461; called by muse, mutect2, varscan2
- ZNF347 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV61967932; called by muse, mutect2, varscan2
- ZNF365 | c.32A>T p.Y11F | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.049); catalogued as COSV67925164; called by muse, mutect2, varscan2
- ZNF570 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 34/349 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV57578423; called by muse, mutect2
- ZNF599 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61395726; called by muse, mutect2
- ZNF653 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV53402334, COSV99542308; called by muse, mutect2, varscan2
- ZNHIT2 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as COSV99659419; called by muse, mutect2
- IGHG4 | c.538T>A p.Y180N | Missense Mutation (SNP) | VAF 59/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- LTBP4 | c.4003C>T p.R1335C (on ENST00000308370 / NM_001042544.1; = p.R1298C on NM_003573.2) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDH17 | c.2624_2624+3del p.X875_splice | Splice Site (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- PHTF1 | c.1147_1149del p.W383del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- RHEB | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- SF3B3 | c.3512dup p.N1172Efs*4 | Frame Shift Ins (INS) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2
- TENM4 | c.3611_3614del p.G1204Afs*60 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- TRBV24-1 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.049); called by muse, mutect2
- TRBV27 | c.10del p.Q4Sfs*11 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- ABCB1 | c.915G>T p.L305= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV55947268; called by muse, mutect2, varscan2
- ABLIM3 | c.1962C>T p.F654= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV58639562, COSV58640456; called by muse, mutect2, varscan2
- AGAP3 | c.1581C>G p.L527= (on ENST00000622464; = p.L563= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs889231399, COSV101257426, COSV99070582; called by muse, mutect2
- AHNAK | c.2013C>T p.V671= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs374314479; called by muse, mutect2
- ANKRD11 | c.5205C>T p.L1735= | Silent (SNP) | VAF 13/203 reads (6%) | catalogued as COSV56357326; called by muse, mutect2
- ARF4 | c.408C>A p.I136= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV57714753; called by muse, mutect2, varscan2
- ARID2 | c.3177G>A p.L1059= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs200399663; called by muse, mutect2, varscan2
- ARMC5 | c.12G>A p.A4= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1339700834, COSV51655424; called by muse, mutect2, varscan2
- ATP12A | c.1782G>A p.P594= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1452581735, COSV54513773; called by muse, mutect2
- BCOR | c.4698C>T p.I1566= (on ENST00000378444 / NM_001123385.2; = p.I1532= on NM_017745.6) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV60703002; called by muse, mutect2, varscan2
- BICD2 | c.546G>A p.S182= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs770320084, COSV100794066, COSV63548263; called by muse, mutect2, varscan2
- BPIFA3 | c.483G>A p.V161= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as COSV64925680; called by muse, varscan2
- BRD3 | c.33G>A p.G11= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV57702148; called by muse, mutect2, varscan2
- BRINP3 | c.1287G>A p.P429= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs777399975, COSV66516993; called by muse, mutect2, varscan2
- CABLES1 | c.1815C>T p.F605= (on ENST00000256925 / NM_001100619.2; = p.F340= on NM_138375.2) | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV56931652; called by muse, mutect2
- CALHM1 | c.324C>T p.L108= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1168844165, COSV61707156; called by muse, mutect2, varscan2
- CBX4 | c.900C>T p.D300= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs758891335, COSV53964942; called by muse, mutect2
- CD109 | c.3882C>G p.L1294= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV54651255, COSV99754575; called by muse, mutect2
- CD9 | c.105C>G p.L35= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV50530063; called by muse, mutect2, varscan2
- CD99L2 | c.606C>G p.V202= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV60935381; called by muse, mutect2, varscan2
- CDSN | c.780C>T p.H260= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs566049981, COSV52537552; called by muse, mutect2
- CHSY3 | c.2625C>T p.V875= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59273981; called by muse, mutect2, varscan2
- CIB2 | c.123C>T p.L41= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs780117405, COSV51947814; called by muse, varscan2
- CKAP5 | c.6075G>A p.E2025= (on ENST00000529230 / NM_001008938.4; = p.E1965= on NM_014756.3) | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV56365372; called by muse, mutect2, varscan2
- CPOX | c.546G>A p.E182= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs761826589, COSV51637738; called by muse, mutect2, varscan2
- CSF1 | c.1443T>C p.H481= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1260242538, COSV60032346; called by muse, mutect2
- CYP2A7 | c.1065G>T p.V355= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV52499211; called by muse, mutect2
- DGKZ | c.2988G>A p.Q996= (on ENST00000454345 / NM_001105540.2; = p.Q808= on NM_003646.4) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV58986237; called by muse, mutect2, varscan2
- DIDO1 | c.3420C>T p.F1140= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV56616521; called by muse, mutect2
- DUSP7 | c.750C>G p.P250= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV56588792; called by muse, mutect2
- EPHA8 | c.2769C>T p.L923= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV51264497; called by muse, mutect2, varscan2
- EXOSC10 | c.984G>C p.L328= | Silent (SNP) | VAF 35/259 reads (14%) | catalogued as COSV58664310; called by muse, mutect2, varscan2
- FATE1 | c.498C>T p.I166= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs770314503, COSV64848897; called by muse, mutect2, varscan2
- FRY | c.7569C>G p.S2523= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV66566991, COSV66573069; called by muse, mutect2, varscan2
- FTSJ3 | c.27G>A p.K9= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV59561810; called by muse, mutect2, varscan2
- GIPR | c.177C>G p.L59= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV54423208, COSV54423522; called by muse, mutect2, varscan2
- GPR161 | c.1428C>T p.I476= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV54788575; called by muse, mutect2
- HK1 | c.969G>A p.R323= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV53855258; called by muse, mutect2
- IFNA7 | c.216G>A p.Q72= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV53330677; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.348G>A p.V116= | Silent (SNP) | VAF 27/538 reads (5%) | called by muse, mutect2
- ILVBL | c.1044C>A p.V348= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV54618451; called by muse, mutect2, varscan2
- KATNB1 | c.714C>G p.L238= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV65559796; called by muse, varscan2
- LAMA5 | c.1962C>T p.P654= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs764079235, COSV53355411, COSV53375142; called by muse, mutect2, varscan2
- LAMC3 | c.1758G>A p.L586= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV63089384; called by muse, mutect2, varscan2
- LMCD1 | c.543G>A p.L181= | Silent (SNP) | VAF 17/267 reads (6%) | catalogued as COSV50087588; called by muse, mutect2
- MAP4K3 | c.54G>A p.L18= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs780697701, COSV55711193; called by muse, mutect2, varscan2
- MICALL1 | c.282C>T p.L94= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs751212781, COSV53239701; called by muse, mutect2, varscan2
- MIDEAS | c.2580G>A p.Q860= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV54093440; called by muse, mutect2
- MKX | c.534C>T p.N178= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as rs973131909, COSV65391761; called by muse, mutect2
- MLXIPL | c.2445C>G p.V815= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100515554; called by muse, mutect2
- MTRR | c.1710G>T p.V570= (on ENST00000264668; = p.V543= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as COSV52942344; called by muse, mutect2
- MVB12A | c.105C>G p.V35= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV57678582; called by muse, mutect2, varscan2
- NAALAD2 | c.930G>A p.K310= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV58959575; called by muse, mutect2, varscan2
- NHEJ1 | c.316C>T p.L106= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55405935; called by muse, mutect2, varscan2
- NLGN2 | c.1122C>G p.L374= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV57209408; called by muse, mutect2
- NRCAM | c.387C>T p.R129= (on ENST00000379028 / NM_001371124.1; = p.R123= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as rs770132892, COSV61031235; called by muse, mutect2, varscan2
- NUP160 | c.2772G>A p.Q924= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV101021585, COSV65853859; called by muse, mutect2, varscan2
- OR1C1 | c.496C>T p.L166= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- OR4D6 | c.420G>C p.V140= | Silent (SNP) | VAF 16/221 reads (7%) | catalogued as COSV100271610, COSV55659290; called by muse, mutect2
- OTC | c.519G>T p.L173= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99234368; called by muse, mutect2
- PAPLN | c.3537C>T p.V1179= (on ENST00000554301; = p.V1152= on NM_173462.4) | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs141113206; called by muse, mutect2, varscan2
- PCDHB7 | c.1257C>T p.I419= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV50757338; called by muse, mutect2, varscan2
- PDCD11 | c.2211G>A p.K737= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV63933343; called by muse, mutect2, varscan2
- PDE9A | c.1674C>T p.D558= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs138550222; called by muse, mutect2, varscan2
- PHF24 | c.228C>T p.R76= | Silent (SNP) | VAF 19/211 reads (9%) | catalogued as rs552360157, COSV54273505; called by muse, mutect2
- PLD3 | c.1002G>A p.E334= | Silent (SNP) | VAF 28/226 reads (12%) | catalogued as rs763500081, COSV52519829; called by muse, mutect2, varscan2
- PTCD1 | c.1821C>T p.I607= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as COSV52861846; called by muse, mutect2, varscan2
- RAI1 | c.4023C>G p.L1341= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs974041074, COSV55390656; called by muse, mutect2, varscan2
- SCN2A | c.2322C>G p.L774= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV51835706, COSV51838016; called by muse, mutect2, varscan2
- SCYL1 | c.534C>A p.I178= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54211202; called by muse, mutect2, varscan2
- SFTPB | c.522C>T p.D174= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV60892888; called by muse, mutect2
- SH3GL1 | c.564G>A p.E188= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as rs749461547, COSV53656306, COSV53656725; called by muse, mutect2, varscan2
- SIX1 | c.762G>A p.S254= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV55959457; called by muse, mutect2, varscan2
- SLITRK3 | c.1245G>C p.L415= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV53846499; called by muse, mutect2, varscan2
- SNTG1 | c.1236C>T p.L412= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV52432002; called by muse, mutect2, varscan2
- SPAG16 | c.1569C>T p.I523= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV59078411; called by mutect2, varscan2
- SRSF1 | c.250C>T p.L84= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1334796072, COSV51964383; called by muse, mutect2, varscan2
- SSTR1 | c.258T>C p.Y86= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV57455329; called by muse, mutect2, varscan2
- STIP1 | c.324G>T p.L108= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV59438583; called by muse, mutect2
- TASOR2 | c.3447C>T p.V1149= | Silent (SNP) | VAF 38/211 reads (18%) | catalogued as COSV60166242; called by muse, mutect2, varscan2
- TGM1 | c.819G>C p.G273= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as CD151320, COSV52862287; called by muse, mutect2, varscan2
- TMEM150A | c.237C>T p.F79= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57817575; called by muse, mutect2, varscan2
- TRIM35 | c.616C>T p.L206= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs568085746, COSV59522522; called by muse, mutect2, varscan2
- UGGT1 | c.1695T>C p.Y565= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV52133383; called by muse, mutect2, varscan2
- VPS13C | c.7863C>G p.V2621= (on ENST00000644861 / NM_020821.3; = p.V2578= on NM_017684.5) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV51132760; called by muse, mutect2, varscan2
- ZDHHC1 | c.1248C>T p.A416= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV52083577; called by muse, mutect2
- ZFYVE28 | c.1419C>T p.L473= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs143269293; called by muse, mutect2
- ZNF560 | c.1659C>T p.F553= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV56866591; called by muse, mutect2, varscan2
- CAPN1 | chr11:65214054 C>G | 3'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2633G>C | Intron (SNP) | VAF 37/269 reads (14%) | catalogued as COSV56001493; called by muse, mutect2, varscan2
- CYP11B1 | c.240-171C>T | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as COSV52825634; called by muse, mutect2, varscan2
- DST | c.4297-4056G>C | Intron (SNP) | VAF 25/109 reads (23%) | catalogued as COSV55003623; called by muse, mutect2, varscan2
- PDXK | c.88-1620G>A | Intron (SNP) | VAF 13/133 reads (10%) | catalogued as COSV52361592; called by muse, mutect2
- PRMT1 | c.91-236G>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
